Gene-level copy-number profile of tumor specimen TCGA-VF-A8AA-01A from TCGA case TCGA-VF-A8AA, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 51.9 years (18,940 days).
Specimen TCGA-VF-A8AA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.49a23ebc-c3e5-4b3a-8ce0-c746bc181b0c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VF-A8AA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/df18e09e-7e47-48e1-bdcd-69abfa3688c9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,804; copy number 2: 46,431; copy number 3: 6,584.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VF-A8AA-01A-11D-A434-01): tumor purity 0.32, ploidy 3.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,418. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
